Somatic mutation profile of tumor specimen MP2PRT-PARXZI-TMP1-A (aliquot MP2PRT-PARXZI-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PARXZI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,026 days).
Specimen MP2PRT-PARXZI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20e85b9c-ba07-4624-9666-8189b5b5cba5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXZI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXZI-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/914d0f62-a189-4ec1-ae6a-14ad2892dd00

The open-access MAF lists 192 somatic variants for this specimen: 141 protein-altering or splice-affecting, 40 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 40, Nonsense Mutation 16, Intron 5, 3'UTR 2, 5'UTR 2, 3'Flank 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 15/345 reads (4%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV52517787, COSV52518375; called by muse, mutect2
- LGI1 | c.386C>G p.S129* | Nonsense Mutation (SNP) | VAF 12/205 reads (6%) | catalogued as rs1564845068; ClinVar: pathogenic; called by muse, mutect2
- AC092143.1 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 221/741 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1264493075; called by muse, mutect2, varscan2
- ACTN4 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 70/350 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.487); catalogued as COSV53144128; called by muse, mutect2, varscan2
- ANKLE1 | c.217G>A p.E73K (on ENST00000394458; = p.E19K on NM_152363.6) | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1301299465; called by muse, mutect2
- APOL5 | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 25/419 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.151); catalogued as COSV50766795; called by muse, mutect2
- ATP13A4 | c.2812C>G p.L938V | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV61328308; called by muse, mutect2
- BEST1 | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 32/422 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV100077436; called by muse, mutect2
- BRCA2 | c.8587G>C p.E2863Q | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66462952; called by muse, mutect2
- CEBPZ | c.3089G>T p.S1030I | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1390572238, COSV52205949; called by muse, mutect2
- CHRNE | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as COSV99544938; called by muse, mutect2
- CIC | c.977C>G p.S326* | Nonsense Mutation (SNP) | VAF 22/364 reads (6%) | catalogued as COSV50650823; called by muse, mutect2
- DACT1 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs768131365; called by muse, mutect2
- DNAH10 | c.4831T>C p.C1611R (on ENST00000409039; = p.C1550R on NM_207437.3) | Missense Mutation (SNP) | VAF 30/462 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs1272100740; called by muse, mutect2
- DNAH6 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 89/229 reads (39%) | catalogued as rs867472657, COSV52874214, COSV52887159; called by muse, mutect2, varscan2
- DNAH9 | c.7861G>A p.D2621N | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1394606403; called by muse, mutect2
- ENDOU | c.863C>T p.S288L (on ENST00000422538 / NM_001172439.2; = p.S247L on NM_006025.4) | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.03); catalogued as COSV57464937, COSV57465932; called by muse, mutect2
- FAHD1 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 196/344 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs1033371445; called by muse, mutect2, varscan2
- GDI1 | c.1302G>C p.M434I | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV50133125; called by muse, mutect2, varscan2
- GUCY1A2 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 23/397 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1203378752; called by muse, mutect2
- HCRTR2 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV63799019; called by muse, mutect2, varscan2
- IL18R1 | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 37/397 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99029324; called by muse, mutect2
- INSRR | c.3857G>C p.R1286T | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100947989, COSV63871354; called by muse, mutect2
- KIF2B | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 163/337 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs762901378, COSV52128005; called by muse, mutect2, varscan2
- KLHL6 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755341184; called by muse, mutect2, varscan2
- KRT28 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs1227861217, COSV60683457; called by muse, mutect2
- MCM9 | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 12/343 reads (3%) | catalogued as rs1427252745, COSV60164889, COSV60165062; called by muse, mutect2
- MGAM | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs782236312, COSV71885941; called by muse, mutect2
- NAV3 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1005877698, COSV57058762; called by muse, mutect2
- NR3C2 | c.1832C>G p.S611* | Nonsense Mutation (SNP) | VAF 45/447 reads (10%) | catalogued as COSV100679753; called by muse, mutect2, varscan2
- NR3C2 | c.1154C>G p.S385* | Nonsense Mutation (SNP) | VAF 14/350 reads (4%) | catalogued as COSV60989648; called by muse, mutect2
- NRAS | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV54738004, COSV54746465; called by muse, mutect2
- NXT2 | c.248-1G>C p.X83_splice (on ENST00000372106 / NM_001242617.2; = p.X138_splice on NM_018698.5) | Splice Site (SNP) | VAF 20/122 reads (16%) | catalogued as COSV99484042; called by muse, mutect2, varscan2
- OR4E2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 137/298 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs369264275; called by muse, mutect2
- PCOLCE2 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs1414304734, COSV55999999; called by muse, mutect2
- PGK1 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV100965370; called by muse, mutect2, varscan2
- PIEZO1 | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 18/592 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as rs976631855, COSV56333101; called by muse, mutect2
- PLEKHG4B | c.3772G>A p.E1258K (on ENST00000283426; = p.E1614K on NM_052909.5) | Missense Mutation (SNP) | VAF 51/326 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.157); catalogued as rs767435235; called by muse, mutect2, varscan2
- PPFIA1 | c.646C>G p.L216V | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99557270; called by muse, mutect2
- PSG8 | c.430C>T p.L144= | Splice Region (SNP) | VAF 15/97 reads (15%) | catalogued as rs1466865677, COSV60610769; called by muse, mutect2, varscan2
- PUM2 | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV57580760; called by muse, mutect2, varscan2
- RETREG3 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 115/315 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.306); catalogued as rs761308861; called by muse, mutect2, varscan2
- RNF39 | c.573G>C p.M191I | Missense Mutation (SNP) | VAF 18/481 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV54992661; called by muse, mutect2
- RPRD1B | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 23/338 reads (7%) | catalogued as COSV65032879; called by muse, mutect2
- RPS6KA5 | c.2011G>T p.D671Y | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100002019, COSV56222285; called by muse, mutect2
- RTL1 | c.1247G>A p.R416K | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs967069517; called by muse, mutect2, varscan2
- RYR3 | c.2935C>T p.Q979* | Nonsense Mutation (SNP) | VAF 61/335 reads (18%) | catalogued as COSV66793527; called by muse, mutect2, varscan2
- SCN10A | c.5606G>A p.R1869H | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs765477377, COSV71860704, COSV71862571; called by muse, mutect2, varscan2
- SCNN1B | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 59/461 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV56303119; called by muse, mutect2, varscan2
- SLC12A5 | c.1981G>C p.E661Q (on ENST00000454036 / NM_001134771.2; = p.E638Q on NM_020708.5) | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV54795957; called by muse, mutect2
- SMAP1 | c.538G>A p.E180K (on ENST00000370455 / NM_001044305.3; = p.E153K on NM_021940.5) | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.476); catalogued as rs1214328224, COSV57643799; called by muse, mutect2, varscan2
- TFAP2C | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV99571634; called by muse, mutect2, varscan2
- THEG | c.815C>G p.S272* | Nonsense Mutation (SNP) | VAF 47/433 reads (11%) | catalogued as COSV100700632; called by muse, mutect2
- TMEM150C | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV71388669; called by muse, mutect2
- TMEM94 | c.3760C>G p.R1254G | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58598860; called by muse, mutect2
- TRIM24 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 28/559 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1418259858; called by muse, mutect2
- TRPM6 | c.4384G>C p.E1462Q | Missense Mutation (SNP) | VAF 39/376 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as COSV62505854; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2, varscan2
- UGT1A10 | c.233C>G p.S78* | Nonsense Mutation (SNP) | VAF 34/264 reads (13%) | catalogued as rs765888404; called by muse, mutect2, varscan2
- VTI1B | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.659); catalogued as COSV99373785; called by muse, mutect2
- ZNF326 | c.1293C>G p.I431M | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.671); catalogued as COSV61036692; called by muse, mutect2, varscan2
- ZNF333 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.773); catalogued as rs756885700; called by muse, mutect2
- ZNF431 | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 6/192 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1282949039; called by muse, mutect2
- ZYX | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs774226385; called by muse, mutect2
- ADPRH | c.96G>C p.K32N | Missense Mutation (SNP) | VAF 17/388 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.144); called by muse, mutect2
- AKAP12 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 18/351 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2
- AP4E1 | c.1411C>G p.L471V | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2
- ATP8A1 | c.414G>C p.L138F | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); called by muse, mutect2
- BRINP3 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- C6orf132 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 90/494 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC103 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 195/472 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.444); called by muse, mutect2
- CCDC103 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 132/294 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.335); called by muse, mutect2
- CCRL2 | c.711C>G p.F237L | Missense Mutation (SNP) | VAF 144/335 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH23 | c.5444C>A p.A1815D | Missense Mutation (SNP) | VAF 46/359 reads (13%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- CDH23 | c.7873G>C p.E2625Q | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CEP85 | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 25/390 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.214); called by muse, mutect2
- CLEC14A | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 106/244 reads (43%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN2 | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 26/446 reads (6%) | called by muse, mutect2
- CNTNAP2 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.093); called by muse, mutect2
- CRYZL1 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2
- CYP1A1 | c.336C>G p.F112L | Missense Mutation (SNP) | VAF 72/426 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- DDX42 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- DNAJC25 | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- DNMT3B | c.1490G>T p.R497L | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAM181B | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 31/625 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FOXN2 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLIPR1L2 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 22/281 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- GPR179 | c.1970C>G p.S657* (on ENST00000621958; = p.S656* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 91/563 reads (16%) | called by muse, mutect2, varscan2
- HAUS1 | c.217C>G p.Q73E | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HJV | c.1174G>C p.E392Q (on ENST00000336751 / NM_213653.4; = p.E279Q on NM_145277.5) | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2
- KCND1 | c.1640C>G p.S547C | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- KCNK13 | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 22/319 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); called by muse, mutect2
- KIF21B | c.95C>G p.S32C | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.819); called by muse, mutect2
- KIF4B | c.3553C>G p.P1185A | Missense Mutation (SNP) | VAF 23/311 reads (7%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2
- LCK | c.574T>G p.Y192D | Missense Mutation (SNP) | VAF 162/393 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LDHD | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 27/584 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.347); called by muse, mutect2
- LRCH1 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- LRR1 | c.756G>C p.K252N | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- MAN1C1 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- MPC1L | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- MYO10 | c.4299G>C p.E1433D | Missense Mutation (SNP) | VAF 62/395 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO5A | c.4258G>C p.E1420Q | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- NFS1 | c.1130C>G p.S377* | Nonsense Mutation (SNP) | VAF 8/206 reads (4%) | called by muse, mutect2
- NOA1 | c.58C>G p.P20A | Missense Mutation (SNP) | VAF 36/499 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.142); called by muse, mutect2
- NOTO | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- ONECUT3 | c.449C>A p.A150E | Missense Mutation (SNP) | VAF 180/367 reads (49%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- OR5A1 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- OR5I1 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 102/251 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- PCDHGA7 | c.726C>G p.F242L | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PCDHGB1 | c.2033C>G p.S678C | Missense Mutation (SNP) | VAF 21/422 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- PDE6B | c.2136G>C p.M712I | Missense Mutation (SNP) | VAF 20/377 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- PGM5 | c.294C>G p.I98M | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- PIEZO1 | c.5187C>A p.F1729L | Missense Mutation (SNP) | VAF 32/429 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PIEZO2 | c.7750G>C p.E2584Q | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PPP2R5A | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 33/324 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2
- PRKD1 | c.1000G>T p.G334W | Missense Mutation (SNP) | VAF 13/265 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- PRRG3 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PSMB2 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- RAPGEF2 | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 23/320 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- RASA2 | c.1536C>G p.F512L | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ROBO2 | c.2377G>A p.D793N | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RSPH1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 57/449 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RTF1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 113/160 reads (71%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- SCN2A | c.5710C>A p.Q1904K | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- SCRIB | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SENP5 | c.999C>G p.F333L | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- SLC40A1 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.899); called by muse, mutect2
- SLCO1A2 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.111); called by muse, mutect2
- SPNS3 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- SYNCRIP | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 20/441 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNJ1 | c.4381G>A p.E1461K | Missense Mutation (SNP) | VAF 17/300 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- TAOK1 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.401); called by muse, mutect2
- TDRD15 | c.4207C>T p.Q1403* | Nonsense Mutation (SNP) | VAF 17/210 reads (8%) | called by muse, mutect2
- TFDP2 | c.973G>C p.E325Q (on ENST00000489671 / NM_001178139.2; = p.E265Q on NM_006286.5) | Missense Mutation (SNP) | VAF 43/316 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- UBR4 | c.9873G>C p.Q3291H | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- UFL1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 181/384 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- UNC5B | c.2796G>C p.K932N | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF17 | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 64/342 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ZNF280A | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 48/456 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ZNF445 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF671 | c.1541G>C p.R514T | Missense Mutation (SNP) | VAF 100/344 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- AJAP1 | c.1023C>T p.P341= | Silent (SNP) | VAF 25/388 reads (6%) | catalogued as rs190578577; called by muse, mutect2
- ATP1A3 | c.1962C>A p.P654= (on ENST00000545399 / NM_001256214.2; = p.P641= on NM_152296.5) | Silent (SNP) | VAF 40/331 reads (12%) | called by muse, mutect2, varscan2
- C15orf61 | c.330C>G p.L110= | Silent (SNP) | VAF 34/372 reads (9%) | called by muse, mutect2
- C6orf132 | c.1323C>G p.L441= | Silent (SNP) | VAF 67/307 reads (22%) | called by muse, mutect2, varscan2
- CCDC136 | c.2496C>A p.V832= | Silent (SNP) | VAF 14/383 reads (4%) | called by muse, mutect2
- CCDC150 | c.879C>G p.L293= | Silent (SNP) | VAF 25/244 reads (10%) | catalogued as rs1257752853; called by muse, mutect2
- CFAP46 | c.3510G>A p.Q1170= | Silent (SNP) | VAF 13/336 reads (4%) | called by muse, mutect2
- EEF2 | c.1434C>T p.F478= | Silent (SNP) | VAF 24/472 reads (5%) | catalogued as COSV58580998; called by muse, mutect2
- GNE | c.915C>A p.P305= (on ENST00000396594 / NM_001128227.3; = p.P274= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/412 reads (6%) | called by muse, mutect2
- GPR179 | c.3663C>T p.V1221= (on ENST00000621958; = p.V1220= on NM_001004334.4) | Silent (SNP) | VAF 52/556 reads (9%) | catalogued as rs746793498; called by muse, mutect2
- LIMK2 | c.1239G>A p.L413= | Silent (SNP) | VAF 32/240 reads (13%) | catalogued as COSV59182965; called by muse, mutect2
- LPAR6 | c.927C>T p.V309= | Silent (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- LRP1B | c.11478C>T p.F3826= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as COSV67208237; called by muse, mutect2
- LRRC66 | c.387C>G p.L129= | Silent (SNP) | VAF 14/322 reads (4%) | called by muse, mutect2
- MAP3K4 | c.3921G>A p.K1307= | Silent (SNP) | VAF 35/370 reads (9%) | catalogued as rs760036794, COSV62336647; called by muse, mutect2
- MAST4 | c.4614G>C p.V1538= (on ENST00000403625 / NM_001164664.2; = p.V1349= on NM_015183.3) | Silent (SNP) | VAF 30/456 reads (7%) | called by muse, mutect2
- MLH1 | c.780C>T p.L260= | Silent (SNP) | VAF 19/253 reads (8%) | catalogued as rs587779038, CX1210136, COSV99212921; ClinVar: likely benign; called by muse, mutect2
- NOLC1 | c.1665G>A p.Q555= | Silent (SNP) | VAF 34/434 reads (8%) | called by muse, mutect2
- NOTCH3 | c.6291C>T p.V2097= | Silent (SNP) | VAF 178/534 reads (33%) | called by muse, mutect2, varscan2
- NR0B1 | c.744C>G p.L248= | Silent (SNP) | VAF 20/287 reads (7%) | catalogued as rs1263620093, COSV100973507; called by muse, mutect2
- OR10H1 | c.216C>G p.L72= | Silent (SNP) | VAF 80/485 reads (16%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1614C>T p.R538= | Silent (SNP) | VAF 302/667 reads (45%) | catalogued as COSV63538652; called by muse, mutect2, varscan2
- PGLYRP3 | c.144C>T p.I48= | Silent (SNP) | VAF 32/396 reads (8%) | called by muse, mutect2
- RFPL4AL1 | c.300C>T p.F100= | Silent (SNP) | VAF 105/662 reads (16%) | catalogued as rs775396712; called by muse, mutect2, varscan2
- RSPH1 | c.18G>A p.S6= | Silent (SNP) | VAF 57/450 reads (13%) | called by muse, mutect2, varscan2
- SACS | c.423G>A p.E141= | Silent (SNP) | VAF 91/196 reads (46%) | called by muse, varscan2
- SCARA5 | c.489C>T p.T163= | Silent (SNP) | VAF 52/646 reads (8%) | catalogued as COSV57276249; called by muse, mutect2
- SMC5 | c.2085G>A p.K695= | Silent (SNP) | VAF 16/330 reads (5%) | called by muse, mutect2
- SOBP | c.2481G>A p.V827= | Silent (SNP) | VAF 16/447 reads (4%) | catalogued as COSV57999323; called by muse, mutect2
- SORBS2 | c.1887C>T p.F629= | Silent (SNP) | VAF 26/616 reads (4%) | called by muse, mutect2
- SOS2 | c.3210G>C p.R1070= | Silent (SNP) | VAF 21/421 reads (5%) | called by muse, mutect2
- SYNE2 | c.6357C>T p.I2119= | Silent (SNP) | VAF 14/359 reads (4%) | called by muse, mutect2
- TAF4 | c.174C>G p.L58= | Silent (SNP) | VAF 40/370 reads (11%) | called by muse, mutect2, varscan2
- TOR4A | c.897C>T p.L299= | Silent (SNP) | VAF 34/554 reads (6%) | catalogued as rs774262607; called by muse, mutect2
- TRANK1 | c.3573G>A p.L1191= | Silent (SNP) | VAF 16/392 reads (4%) | called by muse, mutect2
- TRPM8 | c.960C>T p.I320= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as rs1340039842; called by muse, mutect2, varscan2
- TXNDC16 | c.2160G>T p.L720= | Silent (SNP) | VAF 79/215 reads (37%) | called by muse, mutect2, varscan2
- USP29 | c.2768G>A p.*923= | Silent (SNP) | VAF 15/160 reads (9%) | called by muse, mutect2
- UTP20 | c.8334G>C p.L2778= | Silent (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2, varscan2
- WIZ | c.3888C>T p.L1296= (on ENST00000673675 / NM_001371589.1; = p.L201= on NM_021241.3) | Silent (SNP) | VAF 22/362 reads (6%) | called by muse, mutect2
- CCNP | c.*732C>G | 3'UTR (SNP) | VAF 26/442 reads (6%) | called by muse, mutect2
- COP1 | c.-95C>T | 5'UTR (SNP) | VAF 83/226 reads (37%) | called by muse, mutect2, varscan2
- EBAG9 | c.522-955G>C | Intron (SNP) | VAF 134/316 reads (42%) | catalogued as rs1419499694; called by muse, mutect2, varscan2
- EGFR | c.1881-729C>T | Intron (SNP) | VAF 47/332 reads (14%) | called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442588 G>C | 3'Flank (SNP) | VAF 16/223 reads (7%) | called by muse, mutect2
- N4BP2L2 | chr13:32442589 A>T | 3'Flank (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- PGM3 | c.-2-232C>T | Intron (SNP) | VAF 25/294 reads (9%) | called by muse, mutect2
- PRDM2 | c.*6C>G | 3'UTR (SNP) | VAF 38/218 reads (17%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.3746-2634C>G | Intron (SNP) | VAF 13/389 reads (3%) | called by muse, mutect2
- RGL1 | c.-424G>C | 5'UTR (SNP) | VAF 23/368 reads (6%) | called by muse, mutect2
- USP48 | c.1451-19C>T | Intron (SNP) | VAF 14/410 reads (3%) | called by muse, mutect2
